Somatic mutation profile of tumor specimen TCGA-BQ-7044-01A (aliquot TCGA-BQ-7044-01A-11D-1961-08) from TCGA case TCGA-BQ-7044, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 73.5 years (26,831 days).
Specimen TCGA-BQ-7044-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8aca0e54-6e8a-4c6e-a056-40845423e2b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-7044-11A (Solid Tissue Normal), aliquot TCGA-BQ-7044-11A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0dbab7dc-c844-486f-b720-02d31d27f4be

The open-access MAF lists 77 somatic variants for this specimen: 61 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 47, Silent 16, Frame Shift Del 6, Splice Site 2, Frame Shift Ins 2, Nonsense Mutation 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.245A>G p.E82G | Missense Mutation (SNP) | VAF 39/90 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960018, COSV67961061, COSV67962846; called by muse, mutect2, varscan2
- AFAP1 | c.301A>C p.S101R | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV61796329; called by muse, mutect2, varscan2
- ASAP2 | c.1693G>C p.A565P | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV55633438; called by muse, mutect2, varscan2
- BCAM | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV54301283; called by muse, mutect2, varscan2
- BNC1 | c.1337C>T p.T446M | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs377611889; called by mutect2, varscan2
- C6orf226 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.694); catalogued as COSV59034912; called by muse, mutect2, varscan2
- CDH5 | c.5A>C p.Q2P | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV58518080; called by muse, mutect2, varscan2
- CHCHD3 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV52777166; called by muse, mutect2, varscan2
- CLASP1 | c.4031T>G p.F1344C | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55327536; called by muse, mutect2, varscan2
- CSMD2 | c.3244G>A p.G1082S | Missense Mutation (SNP) | VAF 60/92 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53922969; called by muse, mutect2, varscan2
- DNMBP | c.3350C>G p.P1117R | Missense Mutation (SNP) | VAF 71/206 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60627467; called by muse, mutect2, varscan2
- DPF3 | c.155A>C p.N52T | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63500729, COSV63501516; called by muse, mutect2, varscan2
- ENSA | c.11A>C p.K4T | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.154); catalogued as COSV55026964; called by muse, mutect2, varscan2
- EP400 | c.2246T>A p.I749N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57775638; called by muse, mutect2
- EP400 | c.2248G>C p.A750P | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV57775653; called by muse, mutect2
- EPS15L1 | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs769578542, COSV50169964; called by muse, mutect2, varscan2
- EPS15L1 | c.2094A>T p.L698F | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.429); catalogued as COSV50169988; called by muse, mutect2, varscan2
- EXOC4 | c.2614A>G p.R872G | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54103546; called by muse, varscan2
- FAM71D | c.1172C>A p.T391N | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.12); catalogued as COSV61295849; called by mutect2, varscan2
- FCAR | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 46/116 reads (40%) | catalogued as COSV62030026; called by muse, mutect2, varscan2
- FMO2 | c.963C>A p.N321K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV52947384, COSV52948364; called by muse, mutect2, varscan2
- FN1 | c.926T>G p.V309G | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.732); catalogued as COSV60555569; called by muse, mutect2, varscan2
- GTF3C3 | c.2633C>T p.T878M | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs143599816; called by mutect2, varscan2
- HEATR5B | c.4325C>T p.S1442L | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV51854253; called by muse, mutect2, varscan2
- HORMAD1 | c.178+1G>A p.X60_splice | Splice Site (SNP) | VAF 24/70 reads (34%) | catalogued as COSV59271515; called by muse, varscan2
- KIAA1549 | c.3139C>A p.Q1047K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV54317463; called by muse, mutect2, varscan2
- MGAM | c.2758G>T p.V920F | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.059); catalogued as COSV72074899; called by muse, mutect2, varscan2
- MON2 | c.4080A>G p.I1360M | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs780129721, COSV54809069; called by muse, mutect2, varscan2
- MUC5B | c.300C>G p.N100K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV71593026; called by muse, mutect2, varscan2
- OCA2 | c.2339-2A>T p.X780_splice | Splice Site (SNP) | VAF 20/56 reads (36%) | catalogued as COSV62348609; called by muse, mutect2, varscan2
- P2RX5 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs1370740185, COSV56592335, COSV56594105; called by muse, mutect2, varscan2
- PDLIM1 | c.715A>C p.S239R | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV61474248; called by muse, mutect2, varscan2
- PKHD1 | c.2092G>A p.G698S | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV61881440; called by muse, mutect2, varscan2
- PLCG2 | c.836A>T p.E279V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63871180; called by mutect2, varscan2
- POLG2 | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV73347030; called by muse, mutect2, varscan2
- POLK | c.572A>C p.N191T | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV54036201; called by muse, mutect2, varscan2
- PPP4R4 | c.62T>C p.M21T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV58555541; called by muse, mutect2, varscan2
- PRRC2A | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV63224698; called by muse, mutect2, varscan2
- RGS3 | c.1249C>T p.R417W (on ENST00000350696 / NM_001282923.2; = p.R305W on NM_017790.4) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs200633658, COSV58282039; called by mutect2, varscan2
- SCN5A | c.1676C>T p.T559I | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as rs199473575, COSV100348218; ClinVar: not provided / uncertain significance; called by mutect2, varscan2
- SLC16A9 | c.977T>C p.L326P | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV68099319; called by muse, mutect2, varscan2
- SLK | c.246A>G p.I82M | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59826228; called by muse, mutect2, varscan2
- SMARCAD1 | c.1538A>G p.K513R | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.241); catalogued as COSV62774847; called by muse, mutect2, varscan2
- SREBF1 | c.934A>G p.S312G | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55417368; called by muse, mutect2, varscan2
- THAP12 | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.63); catalogued as COSV52611094; called by muse, varscan2
- THSD4 | c.2806G>C p.E936Q | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55973202; called by muse, mutect2, varscan2
- TTN | c.31402C>T p.H10468Y (on ENST00000591111; = p.H9541Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | PolyPhen benign (0.003); catalogued as COSV60134427; called by muse, mutect2, varscan2
- USP14 | c.45T>G p.F15L | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as COSV55281556; called by muse, mutect2, varscan2
- ZNF30 | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV57854225; called by muse, mutect2
- ZNF608 | c.2188T>A p.S730T | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.306); catalogued as COSV60438719; called by muse, mutect2, varscan2
- ITPKA | c.1080dup p.E361Rfs*7 | Frame Shift Ins (INS) | VAF 25/78 reads (32%) | called by mutect2, pindel, varscan2
- LNX2 | c.1198_1201delinsT p.P400_E401delins* | Nonsense Mutation (DEL) | VAF 48/121 reads (40%) | called by pindel, varscan2*
- NF1 | c.473del p.S158Lfs*7 | Frame Shift Del (DEL) | VAF 41/96 reads (43%) | called by mutect2, pindel, varscan2
- NF1 | c.1921_1922del p.Q642Nfs*6 | Frame Shift Del (DEL) | VAF 51/172 reads (30%) | called by pindel, varscan2
- PARD6B | c.1077_1085del p.Q360_L362del | In Frame Del (DEL) | VAF 19/69 reads (28%) | called by mutect2, pindel, varscan2
- PORCN | c.592del p.A198Hfs*42 (on ENST00000326194 / NM_203475.3; = p.A198Hfs*76 on NM_022825.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/10 reads (100%) | called by mutect2, varscan2
- PPP2R2A | c.1263_1266del p.H421Qfs*12 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- SLC10A4 | c.1311_1312dup p.*438Sfs*13 | Frame Shift Ins (INS) | VAF 12/53 reads (23%) | called by mutect2, varscan2
- TERB2 | c.622del p.I208Lfs*6 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- TEX45 | c.967_969del p.G323del | In Frame Del (DEL) | VAF 21/60 reads (35%) | called by mutect2, pindel, varscan2
- UFSP1 | c.363del p.N122Tfs*8 | Frame Shift Del (DEL) | VAF 82/189 reads (43%) | called by mutect2, pindel, varscan2
- ADAMTS17 | c.540C>T p.I180= | Silent (SNP) | VAF 43/78 reads (55%) | catalogued as rs777273528, COSV51483917; called by muse, mutect2, varscan2
- ATP2C1 | c.696C>T p.V232= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV60757891; called by muse, mutect2, varscan2
- CLIP2 | c.144A>T p.S48= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as COSV56280756; called by muse, mutect2, varscan2
- DLK1 | c.1080C>T p.A360= | Silent (SNP) | VAF 38/85 reads (45%) | catalogued as rs116711857; called by muse, mutect2, varscan2
- ELL | c.1500C>T p.P500= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs200056265, COSV53213434, COSV53214673; called by muse, mutect2, varscan2
- EPS15L1 | c.192T>C p.G64= | Silent (SNP) | VAF 172/442 reads (39%) | catalogued as COSV50170012; called by muse, mutect2, varscan2
- IRX6 | c.180G>A p.A60= | Silent (SNP) | VAF 25/42 reads (60%) | catalogued as rs748112787, COSV51860899; called by muse, mutect2, varscan2
- KBTBD7 | c.1446T>A p.V482= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV65266673; called by muse, mutect2, varscan2
- LZTS1 | c.1719C>T p.A573= | Silent (SNP) | VAF 50/112 reads (45%) | catalogued as rs770286406, COSV56117229; called by muse, mutect2, varscan2
- MAML1 | c.876G>A p.L292= | Silent (SNP) | VAF 58/128 reads (45%) | catalogued as COSV52986398; called by muse, mutect2, varscan2
- PCSK6 | c.1104C>T p.S368= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs376652644; called by muse, mutect2, varscan2
- PDZD2 | c.8424G>A p.L2808= | Silent (SNP) | VAF 51/115 reads (44%) | catalogued as COSV56861422; called by muse, mutect2, varscan2
- PKHD1L1 | c.3894G>A p.K1298= | Silent (SNP) | VAF 72/182 reads (40%) | catalogued as COSV65745546; called by muse, mutect2, varscan2
- RNF213 | c.2928C>G p.A976= | Silent (SNP) | VAF 67/188 reads (36%) | catalogued as COSV60625338; called by muse, mutect2, varscan2
- SIRT7 | c.1170C>T p.C390= | Silent (SNP) | VAF 96/198 reads (48%) | catalogued as COSV58711628; called by muse, mutect2, varscan2
- ZNF609 | c.1182G>T p.G394= | Silent (SNP) | VAF 49/132 reads (37%) | catalogued as COSV58585167; called by muse, mutect2, varscan2
